Surgical pathology report (de-identified scan), TCGA case TCGA-24-1551, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1551-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

APPENDIX, APPENDECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA INVOLVING PERIAPPENDICEAL SOFT TISSUE WITH EXTENSION INTO MUSCULARIS

24-1551
By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material) listed in the diagnosis(s).

***Report Electronically Reviewed and Signed Out By Conversion

Intraoperative Consultation:

FS1: Ovary, right, total abdominal hysterectomy and bilateral salpingo-oophorectomy - "Poorly-differentiated adenocarcinoma, favor mullerian origin,"

Microscopic Description and Comment:

Both ovaries are extensively involved by poorly differentiated papillary serous adenocarcinoma. The tumor is predominantly present in solid nests but focally exhibits intraluminal complexity, papillary architecture, and marked nuclear pleomorphism and multinucleation. The tumor is present on the ovarian surfaces bilaterally. Metastatic papillary serous adenocarcinoma is present in left peritubal soft tissue, in the omentum, on the uterine serosa with focal extension to adjacent myometrium, in the periappendiceal soft tissue with focal extension into adjacent muscularis, in the specimen labelled "small bowel nodule," and in the specimen labelled "sigmoid nodule."

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Serosus adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
5. Tumor IS identified on the ovarian surface(s).
6. Tumor DOES invade the mesovarium.
7. Tumor is present in the adjacent peritubal soft tissue.
8. Tumor invasion of the pelvic soft tissue CANNOT BE EVALUATED.
9. Tumor involvement of the pelvic peritoneum is PRESENT.
10. Metastatic involvement of the EXTRAPELVIC peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the omentum is PRESENT.
12. The maximum dimension of tumor implants outside the true pelvis is 2.5 cm.
13. Metastatic involvement of the uterine serosa is PRESENT.
14. Metastatic involvement of the endometrium is ABSENT.
15. Regional lymph node metastases are ABSENT.
16. The total number of regional lymph nodes examined is 3
17. The total number of metastatically-involved regional lymph nodes is 0.
Extranodal extension by tumor is NOT APPLICABLE; no nodal metastases are present
18. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring greater than 2 cm in greatest dimension.

THE REGIONAL LYMPH NODES are classified as:

NO (Nodes are free of metastases)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

measuring 0.2 x 0.2 x 0.4 cm each. The lymph nodes are bisected and half is placed in a cassette. [REDACTED]

The fifth specimen container is labeled "right external iliac nodes." It contains a single fragment of white and yellow tissue measuring 2.5 x 1.0 x 0.5 cm. Sections show two lymph nodes. The smaller measures 0.2 x 0.2 x 0.2 cm. The larger measures 1.5 x 0.7 x 0.2 cm. The lymph nodes are bisected and half is placed in a cassette [REDACTED]

The sixth specimen container is labeled "left obturator node." It contains a single fragment of yellow and white tissue measuring 3.0 x 1.5 x 1.0 cm. Sections show two lymph nodes measuring 0.5 and 1.5 cm in greatest dimension. The nodes are bisected and half is placed in a cassette [REDACTED]

The seventh specimen container is labeled "sigmoid nodule." It contains a single fragment of fibroadipose tissue measuring 2.5 x 1.0 x 0.5 cm. [REDACTED]

The eighth specimen container is labeled "appendix." It contains an appendix with attached mesoappendix. The appendix measures 5.0 cm in length with a diameter of 0.4 cm. It is stapled at the base. The mesoappendix measures 6.0 cm in length x 1.5 cm x 0.7 cm. It consists of yellow adipose tissue. However, there are multiple areas of well circumscribed white nodules ranging in size from 0.1 to 0.6 cm in greatest dimension consistent with tumor studding. A shave section is taken of the base in the midline portion of the specimen including mesoappendix with tumor studs. Longitudinal section is taken of the tip. Sections demonstrate an unremarkable lumen. [REDACTED]

The ninth specimen container is labeled "small bowel nodule." It contains three unoriented fragments of white-tan tissue measuring 1.5 x 1.5 x 0.5 cm in aggregate. Labeled E. Jar 0. [REDACTED]

Source: NCI Genomic Data Commons file a7829918-1447-47f8-87bc-3a9f4dfbe4a1 (TCGA-24-1551.474AC527-45A2-4258-BEC4-0A48A3B80742.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).